Somatic mutation profile of tumor specimen C3L-01032-01 (aliquot CPT0170510022) from CPTAC case C3L-01032, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.8 years (19,276 days).
Specimen C3L-01032-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa79ec86-fa93-4f6c-afbf-4b6d386c0723.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01032-31 (Blood Derived Normal), aliquot CPT0167270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3df907e7-1bbe-4841-953e-cd739c6fa6fb

The open-access MAF lists 106 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 3, In Frame Del 2, RNA 2, Intron 2, Frame Shift Ins 1, 5'UTR 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.4894_4895del p.S1632Yfs*6 | Frame Shift Del (DEL) | VAF 109/303 reads (36%) | catalogued as rs397507748; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 268/581 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 315/643 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP14 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 183/549 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as rs1211723259, COSV57631271; called by muse, mutect2, varscan2
- ALS2CL | c.2736del p.N913Tfs*26 | Frame Shift Del (DEL) | VAF 206/723 reads (28%) | catalogued as COSV59671270; called by pindel, varscan2
- ARHGEF26 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 129/508 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV62852843; called by muse, mutect2, varscan2
- CCDC144A | c.1928G>C p.C643S | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100138553; called by muse, varscan2
- CUX2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 440/722 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs376298955; called by muse, mutect2, varscan2
- DMAP1 | c.265T>C p.S89P | Missense Mutation (SNP) | VAF 38/1052 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.177); catalogued as rs1347980099; called by muse, mutect2
- EFHB | c.1993C>G p.L665V | Missense Mutation (SNP) | VAF 63/844 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs1332360038, COSV55552797; called by muse, mutect2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 154/708 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- FBXO34 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 30/1074 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs1345251564; called by muse, mutect2
- GLI4 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 468/1949 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100391048; called by muse, mutect2, varscan2
- GPR17 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 342/1085 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs755635107, COSV55756400; called by muse, mutect2, varscan2
- GTF2H4 | c.1271A>C p.H424P | Missense Mutation (SNP) | VAF 132/1301 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV52559148; called by muse, mutect2
- IGDCC3 | c.1453G>C p.V485L | Missense Mutation (SNP) | VAF 327/904 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs552951892; called by muse, mutect2, varscan2
- LCN8 | c.517-5C>T | Splice Region (SNP) | VAF 216/636 reads (34%) | catalogued as rs1042605820; called by muse, mutect2, varscan2
- LMBR1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 152/629 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs200345135, COSV62218025; called by muse, mutect2, varscan2
- LTF | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 103/476 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99210583; called by muse, mutect2, varscan2
- NF2 | c.834G>T p.K278N | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100098489; called by muse, mutect2, varscan2
- OFD1 | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 60/501 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs752818939; called by muse, mutect2, varscan2
- OR51A7 | c.718T>C p.C240R | Missense Mutation (SNP) | VAF 32/904 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1421717037; called by muse, mutect2
- PCDH15 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 186/741 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs573043647, COSV57311329, COSV57330716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB7 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 299/814 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as rs1372083895; called by muse, mutect2, varscan2
- PI4KA | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 15/466 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs1478035031; called by muse, mutect2
- PLEKHM1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 369/1121 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs763911008, COSV101378669; called by muse, mutect2, varscan2
- RGS1 | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 176/702 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66506294; called by muse, mutect2, varscan2
- SLC4A11 | c.2125G>C p.G709R | Missense Mutation (SNP) | VAF 40/1056 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV101195938; called by muse, mutect2
- SPP2 | c.102C>G p.D34E | Missense Mutation (SNP) | VAF 28/570 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs766849944; called by muse, mutect2
- WDFY4 | c.5804G>A p.G1935D | Missense Mutation (SNP) | VAF 154/595 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1189664648; called by muse, mutect2, varscan2
- ZBTB11 | c.2488G>C p.E830Q | Missense Mutation (SNP) | VAF 116/512 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57244586; called by muse, mutect2, varscan2
- ZNF518A | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 59/518 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs782439291; called by muse, mutect2, varscan2
- ABCC1 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 156/630 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ABCC3 | c.556A>T p.I186F | Missense Mutation (SNP) | VAF 141/615 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACAN | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 228/993 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTL7B | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 231/1150 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ADAM10 | c.736-1G>C p.X246_splice | Splice Site (SNP) | VAF 130/545 reads (24%) | called by muse, mutect2, varscan2
- ADGRL3 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 167/815 reads (20%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANGPTL6 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 216/744 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- C3orf38 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 134/632 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CCDC136 | c.2999C>G p.T1000S | Missense Mutation (SNP) | VAF 30/1047 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- CCDC159 | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 43/804 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2
- CDCA2 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 254/857 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FAM71E2 | c.2010G>C p.K670N | Missense Mutation (SNP) | VAF 98/1010 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- FOXP3 | c.172T>A p.S58T | Missense Mutation (SNP) | VAF 111/901 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSD11B1L | c.61A>G p.N21D | Missense Mutation (SNP) | VAF 176/658 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGSF9B | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 122/540 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- INSYN2B | c.713_719del p.D238Vfs*8 | Frame Shift Del (DEL) | VAF 161/939 reads (17%) | called by mutect2, pindel, varscan2
- ITM2C | c.12del p.S5Afs*32 | Frame Shift Del (DEL) | VAF 132/587 reads (22%) | called by mutect2, pindel, varscan2
- LRRC25 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 43/918 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- LRRTM4 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 222/870 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- MT1HL1 | c.170G>C p.C57S | Missense Mutation (SNP) | VAF 110/953 reads (12%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC16 | c.7192G>C p.G2398R | Missense Mutation (SNP) | VAF 200/787 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO15A | c.2169G>T p.E723D | Missense Mutation (SNP) | VAF 350/874 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NF2 | c.835A>T p.K279* | Nonsense Mutation (SNP) | VAF 50/313 reads (16%) | called by muse, mutect2, varscan2
- NR0B1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 259/903 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- NT5C3B | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 80/957 reads (8%) | called by muse, mutect2
- NTHL1 | c.530_544del p.Y177_F181del (on ENST00000219066; = p.Y169_F173del on NM_002528.7 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 68/598 reads (11%) | called by mutect2, pindel, varscan2
- PIH1D1 | c.517T>G p.S173A | Missense Mutation (SNP) | VAF 135/594 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- POU2F2 | c.129+2T>G p.X43_splice | Splice Site (SNP) | VAF 172/512 reads (34%) | called by muse, mutect2, varscan2
- PRR33 | c.926_937del p.V309_P312del | In Frame Del (DEL) | VAF 307/864 reads (36%) | called by mutect2, pindel, varscan2
- RBM20 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 241/870 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNASE13 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 204/850 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPL3 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 214/573 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- RYR3 | c.2953A>G p.K985E | Missense Mutation (SNP) | VAF 201/957 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SON | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 342/1066 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SOST | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 336/1058 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- SRPK3 | c.1147+1G>T p.X383_splice | Splice Site (SNP) | VAF 265/818 reads (32%) | called by muse, mutect2, varscan2
- TBC1D31 | c.3129_3131delinsAA p.R1044Kfs*50 | Frame Shift Del (DEL) | VAF 158/1491 reads (11%) | called by pindel, varscan2*
- TET3 | c.3034_3035insC p.K1012Tfs*41 | Frame Shift Ins (INS) | VAF 114/501 reads (23%) | called by mutect2, pindel, varscan2
- TIAM1 | c.4706C>G p.A1569G | Missense Mutation (SNP) | VAF 101/682 reads (15%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.3125G>C p.R1042P | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC2 | c.1282T>A p.S428T | Missense Mutation (SNP) | VAF 97/621 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNC13C | c.4208A>C p.Q1403P | Missense Mutation (SNP) | VAF 219/683 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UQCRC2 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 25/900 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.142); called by muse, mutect2
- VIPAS39 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 82/838 reads (10%) | called by muse, mutect2
- ZNF208 | c.2808G>T p.K936N | Missense Mutation (SNP) | VAF 121/527 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CEACAM5 | c.126G>A p.P42= | Silent (SNP) | VAF 49/1064 reads (5%) | catalogued as rs781806673; called by muse, mutect2
- FABP1 | c.75G>A p.P25= | Silent (SNP) | VAF 112/477 reads (23%) | catalogued as rs145520267; called by muse, mutect2, varscan2
- FAM47B | c.690T>A p.T230= | Silent (SNP) | VAF 230/828 reads (28%) | called by muse, mutect2, varscan2
- GRIN2C | c.769C>T p.L257= | Silent (SNP) | VAF 382/1323 reads (29%) | called by muse, mutect2, varscan2
- GUCA1C | c.483A>G p.K161= | Silent (SNP) | VAF 204/679 reads (30%) | called by muse, mutect2, varscan2
- IL1RAPL1 | c.1764G>A p.S588= | Silent (SNP) | VAF 238/865 reads (28%) | catalogued as rs745388879, COSV56263381; called by muse, mutect2, varscan2
- KCNC1 | c.1425C>T p.V475= | Silent (SNP) | VAF 250/700 reads (36%) | catalogued as rs755628813, COSV56395720; called by muse, mutect2, varscan2
- KCNN3 | c.90G>A p.Q30= | Silent (SNP) | VAF 258/955 reads (27%) | catalogued as rs1360893418; called by muse, varscan2
- LRRTM4 | c.144G>A p.E48= | Silent (SNP) | VAF 210/719 reads (29%) | catalogued as rs1371045223; called by muse, mutect2, varscan2
- NMB | c.6C>G p.A2= | Silent (SNP) | VAF 119/727 reads (16%) | called by muse, mutect2, varscan2
- OR6Y1 | c.669C>T p.Y223= | Silent (SNP) | VAF 258/843 reads (31%) | catalogued as rs537972026, COSV56928838; called by muse, mutect2, varscan2
- RBM11 | c.81C>T p.Y27= | Silent (SNP) | VAF 20/735 reads (3%) | catalogued as COSV68748311; called by muse, mutect2
- ROBO4 | c.1011G>A p.V337= | Silent (SNP) | VAF 52/859 reads (6%) | called by muse, mutect2
- SDK2 | c.4140C>A p.R1380= | Silent (SNP) | VAF 294/869 reads (34%) | catalogued as rs1163126033; called by muse, mutect2, varscan2
- SEMA3F | c.2103C>T p.A701= | Silent (SNP) | VAF 85/854 reads (10%) | catalogued as rs775821212; called by muse, mutect2, varscan2
- STXBP6 | c.246C>T p.L82= | Silent (SNP) | VAF 165/586 reads (28%) | catalogued as rs374634547; called by muse, mutect2, varscan2
- TRBJ2-6 | c.52C>T p.L18= | Silent (SNP) | VAF 22/852 reads (3%) | catalogued as rs1280183881; called by muse, mutect2
- TSC22D2 | c.1683A>G p.L561= | Silent (SNP) | VAF 307/1004 reads (31%) | catalogued as rs753814825; called by muse, mutect2, varscan2
- TSGA10IP | c.15C>G p.T5= | Silent (SNP) | VAF 133/680 reads (20%) | catalogued as COSV101598412; called by muse, mutect2, varscan2
- TTBK1 | c.237C>T p.A79= | Silent (SNP) | VAF 50/730 reads (7%) | catalogued as rs774455336; called by muse, mutect2
- UNC45B | c.774G>A p.R258= | Silent (SNP) | VAF 152/700 reads (22%) | called by muse, mutect2, varscan2
- VN1R4 | c.540T>G p.R180= | Silent (SNP) | VAF 134/651 reads (21%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.513C>G p.L171= | Silent (SNP) | VAF 24/944 reads (3%) | called by muse, mutect2
- ARHGAP27P2 | n.304A>G | RNA (SNP) | VAF 32/388 reads (8%) | called by muse, mutect2
- ECSIT | c.*25C>T | 3'UTR (SNP) | VAF 103/363 reads (28%) | called by muse, mutect2, varscan2
- MPI | c.844+74_844+76del | Intron (DEL) | VAF 198/853 reads (23%) | catalogued as rs1440664472; called by mutect2, pindel, varscan2
- RSAD1 | c.474+74C>T | Intron (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2, varscan2
- SLC12A2 | c.-2C>G | 5'UTR (SNP) | VAF 20/732 reads (3%) | called by muse, mutect2
- UBTFL2 | n.371T>C | RNA (SNP) | VAF 134/857 reads (16%) | catalogued as rs772588693; called by muse, mutect2, varscan2
